Somatic mutation profile of tumor specimen TCGA-VS-A8EJ-01A (aliquot TCGA-VS-A8EJ-01A-11D-A37N-09) from TCGA case TCGA-VS-A8EJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 60.2 years (22,000 days).
Specimen TCGA-VS-A8EJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 496a719c-61b4-4603-9008-52b27173d48f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A8EJ-10A (Blood Derived Normal), aliquot TCGA-VS-A8EJ-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b5b42bb-57f3-4803-9220-c8835177b5e4

The open-access MAF lists 153 somatic variants for this specimen: 122 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 27, Frame Shift Del 11, Nonsense Mutation 10, Splice Region 4, RNA 3, Splice Site 2, In Frame Del 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 33/35 reads (94%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.940G>C p.D314H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100735825; called by muse, mutect2, varscan2
- ABCC5 | c.2410C>T p.Q804* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99657406; called by muse, mutect2, varscan2
- ABI2 | c.512T>A p.L171Q (on ENST00000295851 / NM_001375719.1; = p.L165Q on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99652178; called by muse, mutect2, varscan2
- ACHE | c.1831T>A p.C611S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99574473; called by muse, mutect2, varscan2
- ACSF2 | c.1831C>T p.R611* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | catalogued as rs895097387, COSV51955284; called by muse, mutect2, varscan2
- ACSS1 | c.1265G>A p.C422Y | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100053976; called by muse, mutect2, varscan2
- ADAM8 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV101291729; called by muse, mutect2, varscan2
- AFG1L | c.499A>G p.M167V | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1204301012, COSV100933980; called by muse, mutect2, varscan2
- AGFG2 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as COSV99499508; called by muse, mutect2, varscan2
- CACNA1F | c.2597C>A p.T866N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV100544333; called by muse, mutect2, varscan2
- CAND2 | c.1312G>T p.V438F (on ENST00000456430 / NM_001162499.2; = p.V345F on NM_012298.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV99929614; called by muse, mutect2, varscan2
- CARF | c.1958A>T p.D653V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.241); catalogued as COSV100247832; called by muse, mutect2, varscan2
- CASP14 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.936); catalogued as rs914741838, COSV55666834, COSV99693063, COSV99693117; called by muse, mutect2, varscan2
- CCAR2 | c.196C>A p.H66N | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99254745; called by muse, mutect2, varscan2
- CCAR2 | c.197A>T p.H66L | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99254748; called by muse, mutect2, varscan2
- CCDC22 | c.419T>A p.L140Q | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.235); catalogued as COSV100879877; called by muse, mutect2, varscan2
- CD72 | c.34T>A p.F12I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99427587; called by muse, mutect2, varscan2
- CDK12 | c.1940A>G p.E647G | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV101420517; called by muse, mutect2, varscan2
- CEP162 | c.1106T>G p.V369G | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as COSV100003255; called by muse, mutect2, varscan2
- CLEC14A | c.250G>T p.G84* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100643649; called by muse, mutect2, varscan2
- CRIM1 | c.428A>T p.N143I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99754215; called by muse, mutect2, varscan2
- CSDE1 | c.2218G>A p.E740K (on ENST00000358528 / NM_001007553.3; = p.E709K on NM_007158.6) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99795762; called by muse, mutect2, varscan2
- CSMD2 | c.6058G>A p.D2020N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765541104, COSV53941546; called by muse, mutect2, varscan2
- DAGLA | c.478A>T p.T160S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.956); catalogued as COSV99944658; called by muse, mutect2, varscan2
- DHX38 | c.3491G>A p.R1164Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1051798890, COSV99194525; called by muse, mutect2, varscan2
- EHMT2 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as COSV100977236; called by muse, mutect2, varscan2
- EP300 | c.4066C>T p.R1356* | Nonsense Mutation (SNP) | VAF 26/42 reads (62%) | catalogued as COSV54332519; called by muse, mutect2, varscan2
- ERO1A | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as COSV101193658; called by muse, mutect2, varscan2
- FANCL | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV99287832; called by muse, mutect2, varscan2
- FNDC1 | c.4857T>G p.N1619K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.535); catalogued as COSV99796496; called by muse, mutect2, varscan2
- FST | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.732); catalogued as rs1237450949, COSV99887401; called by muse, mutect2
- GADL1 | c.1290G>C p.K430N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV99244927; called by muse, mutect2, varscan2
- GDI2 | c.427T>C p.F143L | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.296); catalogued as rs1341150715, COSV101200800; called by muse, mutect2, varscan2
- GDPD2 | c.785+1G>C p.X262_splice | Splice Site (SNP) | VAF 17/20 reads (85%) | catalogued as COSV100978689; called by muse, mutect2, varscan2
- GHRL | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 20/34 reads (59%) | catalogued as COSV99814019; called by muse, mutect2, varscan2
- GLRA3 | c.1096T>A p.F366I | Missense Mutation (SNP) | VAF 137/167 reads (82%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV99927998; called by muse, mutect2, varscan2
- GOLGA2 | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.13); catalogued as COSV57848916, COSV57855001; called by muse, mutect2, varscan2
- GRIA1 | c.1598A>T p.D533V | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV99601756; called by muse, mutect2, varscan2
- IL23R | c.1678T>A p.S560T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV100724886; called by muse, mutect2, varscan2
- INPP5A | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | catalogued as COSV61254341; called by muse, mutect2, varscan2
- IPO9 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.04); catalogued as COSV99819495; called by muse, varscan2
- IQCG | c.828G>C p.Q276H | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV54564804; called by muse, mutect2, varscan2
- KANSL1 | c.1923C>G p.I641M | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.139); catalogued as COSV99294826; called by muse, mutect2, varscan2
- KIF24 | c.2795G>C p.R932T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV99903507; called by muse, mutect2, varscan2
- KIF6 | c.57C>A p.H19Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99760272; called by muse, mutect2, varscan2
- KRT6C | c.746T>A p.L249H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV99360160; called by muse, mutect2, varscan2
- LAMTOR4 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs1458007333, COSV100385615; called by muse, mutect2, varscan2
- LGR6 | c.914C>T p.P305L (on ENST00000367278 / NM_001017403.1; = p.P253L on NM_021636.3) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV99706673, COSV99707695; called by muse, mutect2, varscan2
- LRRK2 | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1356271506, COSV100110954; called by muse, mutect2, varscan2
- MAP3K6 | c.3019G>C p.V1007L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100539549; called by muse, mutect2
- MAPK15 | c.211C>G p.P71A | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV100568057; called by muse, mutect2, varscan2
- MED25 | c.1744C>T p.L582= | Splice Region (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100457878; called by muse, mutect2, varscan2
- MMEL1 | c.483C>A p.D161E | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as COSV99984345; called by muse, mutect2, varscan2
- MOG | c.20C>G p.P7R | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100973100; called by muse, mutect2, varscan2
- MRPL4 | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV99460291; called by muse, mutect2, varscan2
- MYPOP | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.185); catalogued as COSV100447909, COSV100447945; called by muse, mutect2, varscan2
- NAV3 | c.3590C>T p.T1197I | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99894467; called by muse, mutect2, varscan2
- NELL2 | c.57T>C p.V19= | Splice Region (SNP) | VAF 23/75 reads (31%) | catalogued as rs751206765, COSV100420459; called by muse, mutect2, varscan2
- NOTUM | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.479); catalogued as COSV101293821; called by muse, mutect2, varscan2
- NPVF | c.281G>T p.R94M | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56060993, COSV56061427, COSV99760302; called by muse, mutect2, varscan2
- NRF1 | c.870G>C p.Q290H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as COSV99782124; called by muse, mutect2, varscan2
- NRXN3 | c.1682G>T p.R561M (on ENST00000335750 / NM_001330195.2; = p.R188M on NM_004796.6) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV59743304; called by muse, mutect2
- NUFIP2 | c.1424C>G p.P475R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99837622; called by muse, mutect2, varscan2
- OR1J4 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100534316; called by muse, mutect2, varscan2
- PAAF1 | c.781A>G p.K261E | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV100142659; called by muse, mutect2, varscan2
- PENK | c.138+2T>G p.X46_splice | Splice Site (SNP) | VAF 21/88 reads (24%) | catalogued as COSV100152447; called by muse, mutect2, varscan2
- PNPLA8 | c.252G>C p.L84F | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV99993723; called by muse, mutect2, varscan2
- PPP1R26 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.083); catalogued as COSV100778141; called by muse, varscan2
- PRRC2A | c.4106C>T p.S1369F | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs769457025, COSV101051346; called by muse, varscan2
- PTPRC | c.3510G>A p.R1170= | Splice Region (SNP) | VAF 25/36 reads (69%) | catalogued as rs1421608327, COSV100723023; called by muse, mutect2, varscan2
- PYHIN1 | c.1182T>A p.S394R | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100932401; called by muse, mutect2, varscan2
- RAB2B | c.537C>G p.H179Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV101176857; called by muse, mutect2, varscan2
- RGS14 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.14); catalogued as COSV68771769, COSV68772122; called by muse, mutect2
- RIMS3 | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV101013545; called by muse, mutect2, varscan2
- SIGLEC7 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV99978872; called by muse, mutect2, varscan2
- SIGLEC7 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs199757387; called by muse, mutect2, varscan2
- SLC22A10 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100235975; called by muse, mutect2, varscan2
- SLC2A2 | c.255G>C p.E85D | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100049480, COSV58585069; called by muse, mutect2, varscan2
- SLC34A1 | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1489305215, COSV100184087; called by muse, mutect2, varscan2
- SLC44A4 | c.1485C>G p.L495= | Splice Region (SNP) | VAF 8/62 reads (13%) | catalogued as COSV99999218; called by muse, mutect2, varscan2
- SLC5A4 | c.1800G>C p.K600N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.14); catalogued as COSV99832100; called by mutect2, varscan2
- SORBS2 | c.1718C>T p.S573F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs1439858710, COSV99512263, COSV99512334; called by muse, mutect2, varscan2
- SPATA13 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV57975927; called by muse, mutect2
- SPEF2 | c.4830G>T p.E1610D | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.185); catalogued as COSV100289342; called by muse, mutect2, varscan2
- SPHKAP | c.4951A>T p.I1651F (on ENST00000392056 / NM_001142644.2; = p.I1622F on NM_030623.3) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.228); catalogued as COSV100764461; called by muse, mutect2, varscan2
- SPIRE1 | c.643A>T p.N215Y | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs764517052, COSV100563952; called by muse, mutect2, varscan2
- SRSF6 | c.967A>C p.T323P | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV99719815; called by muse, mutect2
- SYNE1 | c.20957G>A p.R6986H (on ENST00000367255 / NM_182961.4; = p.R6915H on NM_033071.3) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772675312, COSV54902227; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNJ1 | c.3052G>A p.E1018K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV100449572; called by muse, mutect2, varscan2
- SYT10 | c.1058A>G p.D353G | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs770692294, COSV99951880; called by muse, mutect2, varscan2
- TBCD | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.718); catalogued as COSV100833650; called by muse, mutect2, varscan2
- TGM2 | c.1477G>C p.A493P | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100821724; called by muse, mutect2, varscan2
- TGM4 | c.262A>T p.N88Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); catalogued as COSV99942582; called by muse, mutect2, varscan2
- TIGD2 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100392445; called by muse, mutect2, varscan2
- TM4SF18 | c.441G>C p.Q147H | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV99938014; called by muse, mutect2, varscan2
- TRAPPC4 | c.159G>C p.Q53H | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100548885; called by muse, mutect2, varscan2
- TSC1 | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100052406; called by muse, mutect2, varscan2
- TTC31 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99282318; called by muse, mutect2, varscan2
- UBR4 | c.4957G>C p.D1653H | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV100921552; called by muse, mutect2, varscan2
- USH2A | c.15020C>A p.P5007Q | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100240691; called by muse, mutect2, varscan2
- WWC2 | c.3284A>C p.Q1095P | Missense Mutation (SNP) | VAF 44/53 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV101331051; called by muse, mutect2, varscan2
- ZBTB48 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1238867150, COSV100039827; called by muse, mutect2, varscan2
- ZFHX4 | c.6005C>T p.T2002M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as rs202076391, COSV51470775, COSV51498593; called by muse, mutect2, varscan2
- ZNF398 | c.1252C>T p.R418W (on ENST00000475153 / NM_170686.3; = p.R247W on NM_020781.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775808659, COSV100247004; called by muse, mutect2, varscan2
- ZNF521 | c.2873A>T p.H958L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100833124; called by muse, mutect2, varscan2
- ZNF584 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100183256, COSV100183395; called by muse, mutect2, varscan2
- ZXDC | c.2161G>T p.A721S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.352); catalogued as COSV100306584; called by muse, mutect2, varscan2
- APPL2 | c.943_959del p.G315Ffs*38 | Frame Shift Del (DEL) | VAF 16/33 reads (48%) | called by mutect2, pindel, varscan2
- ATP10B | c.1678_1708del p.W560Pfs*18 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- C1GALT1C1 | c.152_171del p.D51Gfs*2 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- CPNE6 | c.199_209del p.S67Lfs*8 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- FAM47B | c.1887_1892del p.Q630_V631del | In Frame Del (DEL) | VAF 40/73 reads (55%) | called by mutect2, pindel, varscan2
- FLT1 | c.1286del p.Q429Rfs*24 | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | called by mutect2, pindel, varscan2
- HSDL1 | c.177_195del p.R59Sfs*23 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- HYDIN | c.2927_2938del p.S976_R980delinsW | In Frame Del (DEL) | VAF 2/20 reads (10%) | called by mutect2, pindel
- LRRC74A | c.618_630del p.A208Kfs*22 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- MYLK3 | c.2447_2450del p.P816Lfs*17 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | called by mutect2, pindel, varscan2
- SCAF8 | c.3361_3371delinsTA p.G1121_R1124delins* | Nonsense Mutation (DEL) | VAF 20/35 reads (57%) | called by pindel, varscan2*
- STK39 | c.921del p.K308Sfs*25 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- TMEM106B | c.772_779del p.T258Vfs*5 | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | called by mutect2, pindel, varscan2
- UBASH3A | c.618del p.S207Afs*3 | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | called by mutect2, pindel*, varscan2
- CASR | c.2088G>T p.L696= (on ENST00000490131; = p.L773= on NM_000388.4) | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV99949356; called by muse, mutect2, varscan2
- DNM3 | c.186C>T p.G62= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100798590; called by muse, mutect2, varscan2
- DXO | c.771C>T p.S257= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV61713203; called by muse, mutect2, varscan2
- ELK1 | c.564G>T p.G188= | Silent (SNP) | VAF 30/133 reads (23%) | catalogued as COSV99902305; called by muse, mutect2, varscan2
- GCLC | c.1332G>T p.V444= (on ENST00000643939; = p.V442= on NM_001498.4) | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as COSV99988859; called by muse, mutect2
- GLI1 | c.924C>T p.C308= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV57361559, COSV99954539; called by muse, mutect2, varscan2
- GLRA3 | c.633G>A p.V211= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV99927999; called by muse, mutect2, varscan2
- GPS1 | c.387C>G p.A129= | Silent (SNP) | VAF 17/19 reads (89%) | catalogued as COSV100136115; called by muse, mutect2, varscan2
- GRHL1 | c.846C>T p.I282= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100258094, COSV61410407; called by muse, mutect2, varscan2
- GRN | c.372C>A p.I124= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV99275053; called by muse, mutect2, varscan2
- HARBI1 | c.324T>C p.T108= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs769693436, COSV100365949; called by muse, mutect2, varscan2
- HCN1 | c.1768C>A p.R590= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as COSV100301761, COSV57491725, COSV57514836; called by muse, mutect2, varscan2
- ITGAX | c.2793C>T p.H931= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as rs985017935, COSV51652426; called by muse, mutect2, varscan2
- KATNB1 | c.1221A>G p.P407= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV101109336; called by muse, mutect2, varscan2
- KRT20 | c.867G>A p.L289= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV51425756; called by muse, mutect2, varscan2
- KRTAP21-2 | c.63C>A p.S21= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV100441253, COSV61684214; called by muse, mutect2, varscan2
- MYO7B | c.2781G>C p.G927= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV101268356, COSV67351469; called by muse, mutect2, varscan2
- NNT | c.1161A>G p.L387= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs747451641, COSV99239422; called by muse, mutect2, varscan2
- PRB2 | c.1218T>G p.P406= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV101231477; called by muse, mutect2, varscan2
- RBM19 | c.1470C>T p.A490= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV99926665; called by muse, mutect2, varscan2
- RFWD3 | c.820C>T p.L274= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV100736171; called by muse, mutect2, varscan2
- ROGDI | c.289C>T p.L97= | Silent (SNP) | VAF 52/130 reads (40%) | catalogued as COSV100424487; called by muse, mutect2, varscan2
- SI | c.543T>A p.T181= | Silent (SNP) | VAF 37/303 reads (12%) | catalogued as COSV100016797; called by muse, mutect2, varscan2
- TRANK1 | c.2535C>T p.F845= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs200977390; called by muse, mutect2, varscan2
- TRPV2 | c.2160G>T p.T720= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100641341; called by muse, varscan2
- TUBB6 | c.120G>C p.S40= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV100481182; called by muse, mutect2, varscan2
- WBP2 | c.624C>T p.V208= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99257350; called by muse, mutect2, varscan2
- DUOXA1 | chr15:45118024 del AGGCCTCGGACATCCGCAGGCACC | 3'Flank (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- MIR543 | n.66C>A | RNA (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2, varscan2
- OR3A4P | n.1249C>T | RNA (SNP) | VAF 14/15 reads (93%) | catalogued as rs758506070; called by muse, mutect2, varscan2
- STAG3L2 | n.537C>T | RNA (SNP) | VAF 39/124 reads (31%) | called by muse, mutect2, varscan2
